Somatic mutation profile of tumor specimen TCGA-13-1501-01A (aliquot TCGA-13-1501-01A-01W-0545-08) from TCGA case TCGA-13-1501, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.4 years (18,393 days).
Specimen TCGA-13-1501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7ae3d2a-0255-4bed-9de5-22edd46630e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1501-10A (Blood Derived Normal), aliquot TCGA-13-1501-10A-01W-0546-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0e91124-a4e1-43a9-8f70-5e5aaf1329dd

The open-access MAF lists 91 somatic variants for this specimen: 71 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Nonsense Mutation 4, In Frame Del 2, Splice Site 2, Frame Shift Del 1, 5'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4867T>C p.F1623L (on ENST00000272895 / NM_173076.3; = p.F1305L on NM_015657.3) | Missense Mutation (SNP) | VAF 175/500 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55978612; called by muse, mutect2, varscan2
- ACCSL | c.1177A>T p.T393S | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV66583065; called by muse, mutect2, varscan2
- ACLY | c.3143C>G p.A1048G | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV59863263; called by muse, mutect2, varscan2
- ADGRB2 | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV57079692; called by muse, mutect2, varscan2
- AK3 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.554); catalogued as COSV63347360; called by muse, mutect2, varscan2
- ALB | c.1772G>A p.C591Y | Missense Mutation (SNP) | VAF 137/493 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891083; called by muse, mutect2, varscan2
- ANKRD29 | c.302T>G p.F101C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as COSV52428107; called by muse, mutect2, varscan2
- ART5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs376288672; called by muse, mutect2, varscan2
- ATM | c.8861A>G p.Y2954C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767507047, COSV53730237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.2799G>T p.Q933H (on ENST00000545399 / NM_001256214.2; = p.Q920H on NM_152296.5) | Missense Mutation (SNP) | VAF 116/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57491798; called by muse, mutect2, varscan2
- CACNG6 | c.744G>A p.W248* (on ENST00000252729 / NM_145814.1; = p.W177* on NM_031897.2) | Nonsense Mutation (SNP) | VAF 48/197 reads (24%) | catalogued as COSV53168686; called by muse, mutect2, varscan2
- CCNB3 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs781905774, COSV52071947; called by muse, mutect2, varscan2
- CCNT2 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1346690525, COSV51476421, COSV51477262; called by muse, mutect2, varscan2
- CFAP43 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 146/482 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780074336, COSV53375969; called by muse, mutect2
- CIAO1 | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99302535; called by muse, mutect2
- COL4A6 | c.69A>T p.G23= | Splice Region (SNP) | VAF 176/519 reads (34%) | catalogued as COSV57880831; called by muse, mutect2, varscan2
- CPA4 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55985376; called by muse, mutect2, varscan2
- DAGLB | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV51707286; called by muse, mutect2, varscan2
- DIXDC1 | c.986G>A p.G329D (on ENST00000440460 / NM_001037954.4; = p.G118D on NM_033425.4) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59463851; called by muse, mutect2, varscan2
- DPP4 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 76/350 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV62110494; called by muse, mutect2, varscan2
- EGFR | c.3491A>G p.Q1164R | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.037); catalogued as COSV51855038; called by muse, mutect2, varscan2
- ERMAP | c.893A>T p.Y298F | Missense Mutation (SNP) | VAF 95/412 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV60276293; called by muse, varscan2
- FAM20B | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.977); catalogued as rs1375436062, COSV55382978; called by muse, mutect2, varscan2
- FBXO38 | c.1330T>A p.S444T | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV57030943, COSV57032001; called by muse, mutect2, varscan2
- GCNT4 | c.1197G>T p.R399S | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.729); catalogued as COSV59281862; called by muse, mutect2, varscan2
- GLI2 | c.888C>G p.Y296* | Nonsense Mutation (SNP) | VAF 4/90 reads (4%) | catalogued as COSV100082758, COSV100084250; called by muse, mutect2
- H1-1 | c.284C>G p.T95R | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375118598, COSV55120810; called by muse, mutect2, varscan2
- HCN4 | c.1156T>A p.L386I | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56088277; called by muse, mutect2, varscan2
- HEATR5B | c.3710C>A p.S1237* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV51860153; called by muse, mutect2, varscan2
- KHDRBS1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs777529270, COSV56984001; called by muse, mutect2, varscan2
- KMT2B | c.2099A>G p.N700S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV52892812; called by muse, mutect2, varscan2
- KRT6A | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs1253687191, COSV58108202; called by muse, mutect2, varscan2
- MAB21L1 | c.525A>C p.K175N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV59829111; called by muse, mutect2, varscan2
- MARCHF4 | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.876); catalogued as COSV56103085, COSV56109105; called by muse, mutect2, varscan2
- MCAM | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as COSV50670780, COSV99875369; called by muse, mutect2, varscan2
- MID2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1569462125, COSV53314989; called by muse, mutect2, varscan2
- MORC4 | c.1210A>T p.T404S | Missense Mutation (SNP) | VAF 102/465 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV55247322; called by muse, varscan2
- MROH2B | c.4183T>A p.F1395I | Missense Mutation (SNP) | VAF 186/513 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101270606; called by muse, mutect2, varscan2
- MROH5 | c.3578G>A p.C1193Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61473056; called by muse, mutect2, varscan2
- MTUS2 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV70924064; called by muse, mutect2, varscan2
- NDFIP2 | c.459T>A p.S153R | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV54530690; called by muse, mutect2, varscan2
- OR6S1 | c.201C>G p.N67K | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV57839388; called by muse, mutect2, varscan2
- OR7D4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as COSV58071502; called by muse, mutect2, varscan2
- PARD6A | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs983347310, COSV99537541; called by muse, mutect2
- PCSK2 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs142020979; called by muse, mutect2, varscan2
- PDE3A | c.2555G>C p.S852T | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV62984217; called by muse, mutect2, varscan2
- PER1 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV57922462; called by muse, mutect2, varscan2
- POMGNT1 | c.1072C>G p.H358D | Missense Mutation (SNP) | VAF 47/154 reads (31%) | PolyPhen probably damaging (0.99); catalogued as COSV64341215; called by muse, mutect2, varscan2
- PPP1R3F | c.1144G>C p.V382L | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); catalogued as rs782046406, COSV50020942; called by muse, mutect2, varscan2
- RETREG2 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.86); PolyPhen benign (0.085); catalogued as COSV56089139; called by muse, mutect2, varscan2
- RIDA | c.296-1G>C p.X99_splice | Splice Site (SNP) | VAF 19/105 reads (18%) | catalogued as COSV54705751; called by muse, mutect2, varscan2
- RUFY1 | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV60164233; called by muse, mutect2, varscan2
- SF3B4 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.641); catalogued as COSV54967197; called by muse, mutect2, varscan2
- SLCO1A2 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261550; called by muse, mutect2, varscan2
- STAU1 | c.724G>A p.A242T (on ENST00000371856 / NM_001319135.1; = p.A161T on NM_004602.3) | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61460360; called by muse, mutect2, varscan2
- SYTL3 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV51915934; called by muse, mutect2
- TP53 | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- UBE2Q2 | c.448-1G>T p.X150_splice | Splice Site (SNP) | VAF 31/116 reads (27%) | catalogued as COSV51197161; called by muse, mutect2, varscan2
- USH2A | c.3263G>A p.S1088N | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV56449530; called by muse, mutect2, varscan2
- USP24 | c.3880T>A p.S1294T | Missense Mutation (SNP) | VAF 151/547 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as COSV53780280; called by muse, mutect2, varscan2
- WDFY3 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967788700, COSV99882765; called by muse, mutect2, varscan2
- ZC3H14 | c.833G>C p.R278T | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV51774364; called by muse, mutect2, varscan2
- ZNF184 | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV53006028; called by muse, mutect2, varscan2
- ZNF57 | c.1230T>G p.H410Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60984912; called by muse, mutect2, varscan2
- ZNF746 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61406863; called by muse, mutect2, varscan2
- CP | c.2824_2826del p.P942del | In Frame Del (DEL) | VAF 66/519 reads (13%) | called by mutect2, pindel, varscan2
- GLDC | c.2248_2257del p.L750Tfs*20 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | called by mutect2, pindel, varscan2
- IGHG4 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 23/640 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2
- MYH6 | c.2508C>G p.F836L | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC6A2 | c.1516_1533del p.Q506_F511del | In Frame Del (DEL) | VAF 50/203 reads (25%) | called by mutect2, pindel, varscan2
- TRIM8 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.294); called by mutect2, varscan2
- ABI3BP | c.2781C>T p.D927= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99425952; called by muse, mutect2, varscan2
- ADGRA2 | c.1176G>C p.G392= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV59447977; called by muse, mutect2, varscan2
- ARHGEF11 | c.3366T>A p.G1122= | Silent (SNP) | VAF 66/233 reads (28%) | catalogued as COSV59359287; called by muse, mutect2, varscan2
- ASB12 | c.753C>T p.Y251= | Silent (SNP) | VAF 14/395 reads (4%) | catalogued as COSV100744669; called by muse, mutect2
- CD163L1 | c.369T>C p.A123= | Silent (SNP) | VAF 138/375 reads (37%) | catalogued as rs757689392, COSV58026032; called by muse, mutect2, varscan2
- CR1 | c.3627C>G p.T1209= | Silent (SNP) | VAF 18/546 reads (3%) | catalogued as COSV100887480; called by muse, mutect2
- EIF2B3 | c.1020C>G p.V340= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV64519027; called by muse, mutect2, varscan2
- FAM124A | c.1338C>G p.P446= (on ENST00000322475 / NM_001242312.2; = p.P482= on NM_145019.4) | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99696221; called by muse, mutect2, varscan2
- FAM161A | c.879C>G p.L293= | Silent (SNP) | VAF 87/361 reads (24%) | catalogued as COSV56769128; called by muse, mutect2, varscan2
- FER1L5 | c.4182C>T p.Y1394= (on ENST00000623019; = p.Y1367= on NM_001293083.2) | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV67607235; called by muse, mutect2, varscan2
- GNL1 | c.699T>C p.A233= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as COSV64835612; called by muse, mutect2, varscan2
- KLHDC8A | c.351C>G p.A117= | Silent (SNP) | VAF 108/311 reads (35%) | catalogued as COSV65679471; called by muse, mutect2, varscan2
- MDGA2 | c.2229C>A p.G743= (on ENST00000399232 / NM_001113498.2; = p.G445= on NM_182830.4) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV62118670; called by muse, mutect2, varscan2
- POP1 | c.2436G>A p.L812= | Silent (SNP) | VAF 66/573 reads (12%) | catalogued as rs747381391, COSV62894382; called by muse, mutect2, varscan2
- SMARCA4 | c.1428C>A p.L476= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV60811109; called by muse, mutect2, varscan2
- TAS2R38 | c.594C>T p.C198= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV101516385; called by muse, mutect2
- TLE5 | c.243C>T p.I81= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs199751376; called by muse, mutect2
- TTC12 | c.1917G>A p.A639= | Silent (SNP) | VAF 280/790 reads (35%) | catalogued as rs147254715; called by muse, varscan2
- FAM78A | c.-1A>C | 5'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100953406; called by muse, mutect2, varscan2
- MIR519E | n.25G>A | RNA (SNP) | VAF 16/240 reads (7%) | catalogued as rs1199021002; called by muse, mutect2
